Surgical pathology report (de-identified scan), TCGA case TCGA-55-6986, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6986-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Histopathological Examination

Path#: [REDACTED]

Pre-Op Diagnosis : Lung Cancer
Order Physician : [REDACTED]
Specimens : Lung, Right Lower Lobe
Lymph Node, St 8, Paraesophageal
Lymph Node, St 11, Interlobar

Frozen Diagnosis :

Report : GROSS EXAMINATION.

A. The specimen is received in a container labeled with the name of the patient and labeled as lung, right lower lobe. The specimen consists of a lobe of lung 15.0 x 10.0 x 5.5 cm and weighs 120 g. The bronchial margin is submitted in block one. At the edge of the base of the lung the pleura has an umbilicated area with a subjacent tan firm mass measuring 2.5 x 2.0 x 2.0 cm. The mass is approximately 5 cm from the bronchial margin. Sections of the mass are submitted in blocks two through five. Peribronchial lymph nodes are submitted in block six. A random section of lung is submitted in blocks seven.

B. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station eight, paraesophageal. The specimen consists of a fragment of red-black soft tissue measuring 1.2 x 0.7 x 0.3 cm. The specimen is totally submitted.

C. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station 11, interlobar. The specimen consists of a fragment of red-black soft tissue measuring 0.7 x 0.6 x 0.3 cm. The specimen is totally submitted. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. SPECIMEN TYPE: Lobectomy.
LATERALITY: Right.
TUMOR SITE: Lower lobe.
TUMOR SIZE GREATEST DIMENSION: 2.5 cm.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path # [REDACTED]
Visit # [REDACTED]

Page 1 of 2

[page 2 of 2]
ADDITIONAL DIMENSIONS: 2.0 x 2.0 cm.

HISTOLOGIC TYPE: Invasive adenocarcinoma, with bronchioloalveolar features.

HISTOLOGIC GRADE: Grade I-II: Well to moderately differentiated.

PRIMARY TUMOR (PT): pT2: Tumor invades the visceral pleura.

REGIONAL LYMPH NODES (PN): pN0: No regional lymph node metastasis in 3 peribronchial lymph nodes, 1 station 8 paraesophageal lymph node (specimen B), and 1 station 11 interlobar lymph node (specimen C).

DISTANT METASTASIS: pMX: Cannot be assessed.

MARGINS: Margins uninvolved by invasive carcinoma.

The tumor measures 5 cm from the bronchial resection margin.

DIRECT EXTENSION OF TUMOR: None identified.

VENOUS (LARGE VESSEL) INVASION (V): Absent.

ARTERIAL (LARGE VESSEL) INVASION: Absent.

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.

ADDITIONAL PATHOLOGIC FINDINGS: Central scar associated with the adenocarcinoma.

B. Lymph node, station 8, paraesophageal: One lymph node showing sinus histiocytosis with anthracosis. No metastatic carcinoma is identified.

C. Lymph node, station 11, interlobar: One lymph node negative for metastatic carcinoma.

Intradepartmental consultation was obtained.

Pathologist

Source: NCI Genomic Data Commons file cc79f874-81cb-4653-a800-b985b7267332 (TCGA-55-6986.BC8C1075-8F74-42DA-BC09-80B4152B160F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).